Somatic mutation profile of tumor specimen TCGA-66-2794-01A (aliquot TCGA-66-2794-01A-01D-1267-08) from TCGA case TCGA-66-2794, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 64.9 years (23,710 days).
Specimen TCGA-66-2794-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f105a41-1f1f-424f-ae60-0619e933a6a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2794-11A (Solid Tissue Normal), aliquot TCGA-66-2794-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df9e5c77-1c23-40b3-a185-21ab0b3f2e17

The open-access MAF lists 165 somatic variants for this specimen: 131 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 31, Nonsense Mutation 9, Frame Shift Del 2, Splice Site 1, Translation Start Site 1, 3'Flank 1, RNA 1, 5'UTR 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2A | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1555488144, CM138232, COSV58027880, COSV58051418; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 62/97 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1824C>A p.S608R | Missense Mutation (SNP) | VAF 150/454 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55296432; called by muse, mutect2, varscan2
- AIDA | c.234+1G>T p.X78_splice | Splice Site (SNP) | VAF 153/262 reads (58%) | catalogued as COSV60665168; called by muse, mutect2, varscan2
- AKNA | c.3167C>T p.P1056L | Missense Mutation (SNP) | VAF 133/222 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs139913868, COSV56339400; called by muse, mutect2, varscan2
- AL592490.1 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.184); catalogued as COSV69427401; called by muse, mutect2, varscan2
- ANGEL2 | c.545A>G p.D182G | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs781394198, COSV64738008; called by muse, mutect2, varscan2
- AP5S1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs1292535465, COSV55694514; called by muse, mutect2, varscan2
- ASL | c.1172C>A p.S391Y | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59189160; called by muse, mutect2, varscan2
- ATRNL1 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61813257; called by muse, mutect2, varscan2
- BBS9 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54181704; called by muse, mutect2, varscan2
- BSN | c.3388C>A p.P1130T | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV56525105; called by muse, mutect2, varscan2
- CA4 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56282358; called by muse, mutect2, varscan2
- CABP2 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV53709504; called by muse, mutect2, varscan2
- CCDC141 | c.1964A>G p.N655S | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55368346; called by muse, mutect2, varscan2
- CCDC191 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 147/492 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV55675193; called by muse, mutect2, varscan2
- CEP135 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57262119; called by muse, mutect2, varscan2
- CHIT1 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55149091; called by muse, varscan2
- CHST6 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV60001096; called by muse, mutect2, varscan2
- CIZ1 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 63/99 reads (64%) | catalogued as COSV52971325; called by muse, mutect2, varscan2
- CLCN7 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1013856684, COSV51972932; called by muse, mutect2, varscan2
- CLEC18C | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV100032145; called by mutect2, varscan2
- CLN3 | c.742C>T p.R248W (on ENST00000360019 / NM_001286104.2; = p.R272W on NM_000086.2) | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs113041302, COSV61107280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT4 | c.1094C>T p.P365L (on ENST00000315544 / NM_001190848.1; = p.P362L on NM_013316.4) | Missense Mutation (SNP) | VAF 151/321 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1324650797, COSV59657351; called by muse, mutect2, varscan2
- CNTNAP2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs763419157, COSV62237803; called by muse, mutect2, varscan2
- CSMD1 | c.7585G>C p.E2529Q (on ENST00000520002; = p.E2528Q on NM_033225.6) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV59311907; called by muse, mutect2, varscan2
- CTNNA3 | c.2575A>T p.I859F | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs766896063, COSV65528227; called by muse, mutect2, varscan2
- CTNNA3 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV65610870, COSV65622471; called by muse, mutect2
- CTNNB1 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as COSV62713347; called by muse, mutect2, varscan2
- CTNND2 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.879); catalogued as rs1252461309, COSV58915383; called by muse, mutect2, varscan2
- CUL1 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57391468; called by muse, mutect2, varscan2
- DLGAP2 | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 76/132 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs200420347, COSV70096649, COSV70102718; called by muse, mutect2, varscan2
- DNAH10 | c.7099A>T p.K2367* (on ENST00000409039; = p.K2306* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as COSV68999217; called by muse, mutect2, varscan2
- EEF1G | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs368954257; called by muse, mutect2, varscan2
- ELF1 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 151/266 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1329868020, COSV53501704; called by muse, mutect2, varscan2
- ENPP5 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV57909641; called by muse, mutect2, varscan2
- EPPK1 | c.2919C>G p.I973M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV73262251; called by muse, mutect2, varscan2
- ERICH3 | c.2281C>A p.Q761K | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1170742563, COSV58614932; called by muse, mutect2, varscan2
- FAM209B | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100990952; called by muse, mutect2
- FMNL3 | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53306169; called by muse, mutect2, varscan2
- FN1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60550098, COSV60560825; called by muse, mutect2
- FRS2 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54728563; called by muse, mutect2, varscan2
- GDF15 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs754567391, COSV53251545; called by muse, mutect2, varscan2
- GDPD4 | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60021852; called by muse, mutect2, varscan2
- GK2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62626694; called by muse, mutect2, varscan2
- GOLGA6A | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 54/327 reads (17%) | catalogued as rs764510238, COSV51806664; called by muse, mutect2, varscan2
- HCLS1 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV58855927, COSV58859311; called by muse, mutect2, varscan2
- HDAC4 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV61873301; called by muse, mutect2, varscan2
- IQCG | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 87/784 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV54564804; called by muse, mutect2, varscan2
- IRF2BP2 | c.1691G>T p.W564L | Missense Mutation (SNP) | VAF 201/341 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100784369, COSV64015505; called by muse, varscan2
- ITGB1 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.79); PolyPhen probably damaging (1); catalogued as rs200536241, COSV56485465; called by muse, mutect2, varscan2
- KANK1 | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs754470891, COSV63214435; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- KATNB1 | c.1214C>A p.A405E | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV65552577; called by muse, mutect2, varscan2
- KCNC2 | c.1790A>C p.K597T | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV54376393; called by muse, mutect2, varscan2
- KIAA1549 | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.265); catalogued as rs368584498; called by muse, mutect2, varscan2
- KIAA1755 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367812234, COSV54079454; called by muse, mutect2, varscan2
- KLHL6 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 50/1668 reads (3%) | SIFT tolerated (0.9); PolyPhen benign (0.031); catalogued as rs932549092, COSV58067601; called by muse, mutect2
- LAMA2 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 47/174 reads (27%) | catalogued as COSV70344837, COSV70353136; called by muse, mutect2, varscan2
- LRRC46 | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV51637051; called by muse, mutect2, varscan2
- MAGEB1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66776036; called by muse, mutect2, varscan2
- MAGI2 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs779649509, COSV100833252, COSV62639405; called by muse, mutect2, varscan2
- MASP1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 93/1042 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV61829664; called by muse, mutect2
- MED22 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs782286256, COSV59299360; called by muse, mutect2, varscan2
- MEX3C | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV68530360; called by muse, mutect2, varscan2
- MRPS30 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753672352, COSV50181818; called by muse, mutect2, varscan2
- MSI2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs201389280, COSV52365539; called by muse, mutect2, varscan2
- NAA11 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV54515520; called by muse, mutect2
- NRXN1 | c.2759C>A p.T920N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58481404; called by muse, mutect2, varscan2
- NTN1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as rs1428238477, COSV51486447; called by muse, mutect2, varscan2
- NUP155 | c.3663G>A p.W1221* (on ENST00000231498 / NM_153485.3; = p.W1162* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 94/245 reads (38%) | catalogued as COSV51533413; called by muse, mutect2, varscan2
- OR4F6 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV61027361; called by muse, mutect2
- OR5B12 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV56906260; called by muse, mutect2, varscan2
- OR5J2 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.118); catalogued as COSV56622692; called by muse, mutect2, varscan2
- OR9G1 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV56453317; called by muse, mutect2
- OSGIN2 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV52410910; called by muse, mutect2, varscan2
- P2RY1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59309156; called by muse, mutect2, varscan2
- PAPPA2 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV62784167; called by muse, mutect2, varscan2
- PDZRN3 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV55211956; called by muse, mutect2, varscan2
- PHYH | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV53817613; called by muse, mutect2, varscan2
- PKD1 | c.8408G>T p.G2803V | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV51922811; called by muse, mutect2, varscan2
- PKHD1L1 | c.7872G>T p.M2624I | Missense Mutation (SNP) | VAF 277/617 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65750117; called by muse, mutect2, varscan2
- PLB1 | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59833216; called by muse, mutect2
- PLCH1 | c.3826G>A p.E1276K (on ENST00000340059 / NM_001130960.2; = p.E1268K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/369 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1417591220, COSV58207497; called by muse, mutect2, varscan2
- PLXNA4 | c.4047G>T p.E1349D | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV58152556; called by muse, mutect2, varscan2
- PNPLA7 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53004783; called by muse, mutect2, varscan2
- POU3F2 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100099413, COSV100099524, COSV60409436; called by muse, mutect2, varscan2
- PPP1R16B | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55380577, COSV55382421; called by muse, mutect2, varscan2
- PRAMEF14 | c.1391C>A p.P464Q | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); catalogued as COSV100577284; called by muse, mutect2, varscan2
- PTDSS1 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61266028; called by muse, mutect2, varscan2
- RAD9B | c.477G>C p.M159I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV63778519; called by muse, mutect2
- RBMXL2 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs750977558, COSV60980025; called by muse, mutect2, varscan2
- RGPD1 | c.4048A>T p.R1350* (on ENST00000409776; = p.R1358* on NM_001024457.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 140/510 reads (27%) | catalogued as COSV67963225; called by muse, mutect2, varscan2
- RIMS2 | c.4166C>G p.S1389C (on ENST00000666250 / NM_001348490.2; = p.S960C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 245/443 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51649892, COSV51712228; called by muse, mutect2, varscan2
- RPAP1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV58540607; called by muse, mutect2, varscan2
- SGK1 | c.52A>T p.R18W | Missense Mutation (SNP) | VAF 85/359 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV52813810; called by muse, mutect2, varscan2
- SHQ1 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100345515, COSV57764704; called by muse, mutect2, varscan2
- SIGLEC1 | c.2189A>T p.N730I | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV52470049; called by muse, mutect2, varscan2
- SLC14A2 | c.874C>G p.Q292E | Missense Mutation (SNP) | VAF 176/413 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54913313; called by muse, mutect2, varscan2
- SLC25A31 | c.694G>C p.V232L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV55420884; called by muse, mutect2, varscan2
- SLC25A5 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 197/364 reads (54%) | catalogued as COSV100510308; called by mutect2, varscan2
- SLC5A11 | c.654G>C p.L218F | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61743168; called by muse, mutect2, varscan2
- SLCO1B1 | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 79/230 reads (34%) | catalogued as COSV57015312, COSV99078620; called by muse, mutect2, varscan2
- SMAD2 | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.365); catalogued as COSV51032312; called by muse, mutect2, varscan2
- SNRPN | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as COSV57599704; called by muse, mutect2, varscan2
- SOGA1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV52910568; called by muse, mutect2, varscan2
- SOGA1 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV52927660; called by muse, varscan2
- SPP2 | c.472C>G p.H158D | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV51446380; called by muse, mutect2, varscan2
- SRCAP | c.7282C>T p.R2428C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs755641907, COSV52678758; called by muse, mutect2, varscan2
- SRRM4 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57423840; called by muse, mutect2, varscan2
- STAU2 | c.391C>T p.R131W (on ENST00000524300 / NM_001164380.2; = p.R99W on NM_014393.2) | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772107340, COSV63310719; called by muse, mutect2, varscan2
- SYNE1 | c.24403G>A p.E8135K (on ENST00000367255 / NM_182961.4; = p.E8064K on NM_033071.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55067724; called by muse, mutect2, varscan2
- TCTN2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 117/508 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV57634339; called by muse, mutect2, varscan2
- TEX26 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 125/218 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66840510; called by muse, mutect2, varscan2
- THSD7B | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55724577; called by muse, mutect2, varscan2
- THSD7B | c.2231G>T p.S744I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759889842, COSV55724590, COSV55741981; called by muse, mutect2, varscan2
- TLR7 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV66125195; called by muse, mutect2, varscan2
- TRPA1 | c.3074G>C p.C1025S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51570837; called by muse, mutect2, varscan2
- TRPA1 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs762189736, COSV51570859; called by muse, mutect2, varscan2
- USP34 | c.4945G>C p.D1649H | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV101276899, COSV68404783; called by muse, mutect2, varscan2
- USP42 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs1003930563, COSV60358151; called by muse, mutect2, varscan2
- UTP3 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as rs139549167, COSV54661679; called by muse, mutect2, varscan2
- VGLL3 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.914); catalogued as COSV67354117; called by muse, mutect2, varscan2
- VMP1 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51871081; called by muse, mutect2, varscan2
- YBX3 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as COSV54386645; called by muse, mutect2, varscan2
- ZCCHC12 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 93/145 reads (64%) | SIFT tolerated (0.62); PolyPhen benign (0.044); catalogued as rs201023696, COSV59572643, COSV59573208; called by muse, mutect2, varscan2
- ZNF836 | c.1515A>T p.K505N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59085558; called by muse, mutect2
- CD109 | c.646_659delinsG p.Y216Gfs*12 | Frame Shift Del (DEL) | VAF 35/111 reads (32%) | called by pindel, varscan2*
- CR2 | c.1222_1223del p.K408Gfs*7 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | called by mutect2, pindel, varscan2
- HEXD | c.1455_*26del | Nonstop Mutation (DEL) | VAF 20/148 reads (14%) | called by mutect2, pindel
- POTEA | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PPP6R2 | c.359_360insG p.A121Rfs*68 | Frame Shift Ins (INS) | VAF 155/862 reads (18%) | called by mutect2, pindel*, varscan2
- ADAD1 | c.1626T>A p.S542= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as COSV56646426; called by muse, mutect2, varscan2
- ADAM12 | c.1317C>T p.D439= | Silent (SNP) | VAF 99/379 reads (26%) | catalogued as COSV64112401; called by muse, mutect2, varscan2
- ADARB2 | c.1083C>T p.F361= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs752704860, COSV67223232; called by muse, mutect2, varscan2
- AGAP3 | c.253C>T p.L85= (on ENST00000622464; = p.L121= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/283 reads (41%) | catalogued as COSV58995964; called by muse, mutect2, varscan2
- AICDA | c.195C>T p.I65= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as rs371803016; called by muse, mutect2, varscan2
- ANAPC2 | c.1404G>A p.Q468= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as COSV60571855; called by muse, mutect2, varscan2
- APOB | c.3648C>T p.V1216= | Silent (SNP) | VAF 94/355 reads (26%) | catalogued as COSV51947609; called by muse, mutect2, varscan2
- CACNA2D2 | c.3159C>G p.L1053= (on ENST00000479441 / NM_001174051.3; = p.L1046= on NM_006030.4) | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs1303270128, COSV56567778; called by muse, mutect2
- CAPN9 | c.561G>A p.L187= | Silent (SNP) | VAF 54/201 reads (27%) | catalogued as COSV55238089; called by muse, varscan2
- CD36 | c.297C>A p.A99= | Silent (SNP) | VAF 71/178 reads (40%) | catalogued as COSV59217983; called by muse, mutect2, varscan2
- CEACAM20 | c.1344C>T p.I448= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs755217171, COSV57602855; called by muse, mutect2, varscan2
- DCDC1 | c.3900A>G p.E1300= (on ENST00000597505 / NM_001367979.1; = p.E407= on NM_020869.3) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1163187172, COSV58002128; called by muse, mutect2, varscan2
- EDEM2 | c.1599A>T p.T533= | Silent (SNP) | VAF 273/849 reads (32%) | catalogued as COSV63259706; called by muse, mutect2, varscan2
- EEF1G | c.345C>T p.F115= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1476726847, COSV57748252; called by muse, mutect2, varscan2
- EPPK1 | c.4008C>G p.L1336= | Silent (SNP) | VAF 40/221 reads (18%) | catalogued as COSV73262250; called by muse, mutect2, varscan2
- HBS1L | c.2007C>T p.Y669= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as rs567806855, COSV63202524; called by muse, mutect2, varscan2
- IL17A | c.180C>G p.P60= | Silent (SNP) | VAF 84/261 reads (32%) | catalogued as COSV100391528, COSV60683795, COSV60685238; called by muse, mutect2, varscan2
- MARCHF10 | c.141C>G p.R47= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as COSV60889844, COSV60890476; called by muse, mutect2, varscan2
- MICALL2 | c.456A>G p.L152= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs936198915, COSV52517892; called by muse, varscan2
- MMP2 | c.258A>C p.T86= | Silent (SNP) | VAF 65/249 reads (26%) | catalogued as COSV54604211; called by muse, mutect2, varscan2
- NRROS | c.177C>A p.A59= | Silent (SNP) | VAF 27/210 reads (13%) | catalogued as COSV60747245; called by muse, mutect2, varscan2
- OSBPL6 | c.765G>T p.S255= | Silent (SNP) | VAF 97/329 reads (29%) | catalogued as rs763083631, COSV51919425, COSV51927088; called by muse, mutect2, varscan2
- PBX2 | c.1032C>T p.G344= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as rs1339321768, COSV66709277; called by muse, mutect2, varscan2
- RFPL4B | c.270C>G p.L90= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV71437721, COSV71437798; called by muse, mutect2, varscan2
- SLC5A7 | c.204C>T p.I68= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV50896091; called by muse, mutect2, varscan2
- TFB1M | c.21C>G p.L7= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as rs1370112832, COSV65698218; called by muse, mutect2, varscan2
- TLR3 | c.1314G>T p.L438= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV57169955; called by muse, mutect2, varscan2
- TONSL | c.1647G>A p.V549= | Silent (SNP) | VAF 44/212 reads (21%) | catalogued as rs1228979056, COSV68049080; called by muse, mutect2, varscan2
- TTC33 | c.606A>G p.P202= | Silent (SNP) | VAF 58/219 reads (26%) | catalogued as COSV61802875; called by muse, mutect2, varscan2
- UBE3C | c.1983G>T p.P661= | Silent (SNP) | VAF 71/156 reads (46%) | catalogued as COSV61955125; called by muse, mutect2, varscan2
- ZNF646 | c.1845G>A p.R615= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV56217945; called by muse, mutect2, varscan2
- AC074085.2 | n.210G>C | RNA (SNP) | VAF 49/184 reads (27%) | catalogued as rs1432869403; called by muse, mutect2, varscan2
- FICD | c.-1G>C | 5'UTR (SNP) | VAF 40/215 reads (19%) | catalogued as COSV100840298; called by muse, mutect2, varscan2
- SNX18 | chr5:54543343 ins T | 3'Flank (INS) | VAF 36/166 reads (22%) | called by mutect2, pindel, varscan2
